Somatic mutation profile of tumor specimen 0DIW83 from CCDI case PBBWBP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 12.7 years (4,641 days).
Specimen 0DIW83: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dea8975f-7cb6-447b-855b-32c354a1420b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIW66 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca570e77-adcf-42cc-90e5-08872207cb5a

The open-access MAF lists 22 somatic variants for this specimen: 19 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Nonsense Mutation 2, Frame Shift Ins 2, 3'UTR 1, Silent 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.275A>T p.D92V | Missense Mutation (SNP) | VAF 242/283 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM132264, COSV64288500, COSV64301396, COSV64302611; called by muse, mutect2, varscan2
- NOVA1 | c.101dup p.E35* | Frame Shift Ins (INS) | VAF 139/306 reads (45%) | catalogued as rs765756993; called by mutect2, varscan2
- PLXNB1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 138/326 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs760971221; called by muse, mutect2, varscan2
- SLC16A12 | c.39G>T p.K13N | Missense Mutation (SNP) | VAF 416/477 reads (87%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as rs745442164; called by muse, varscan2
- SLC9A9 | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 254/626 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV57227216; called by mutect2, varscan2
- SNTG2 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 240/549 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.41); catalogued as rs754085301, COSV57989621; called by muse, mutect2, varscan2
- STAG2 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 186/208 reads (89%) | catalogued as COSV54351672; called by muse, mutect2, varscan2
- USP6 | c.3752dup p.S1252Qfs*12 | Frame Shift Ins (INS) | VAF 245/715 reads (34%) | catalogued as rs754083634; called by mutect2, varscan2
- ZFHX3 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 374/867 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs755455411, COSV51724318; called by muse, mutect2
- ZFP57 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 260/526 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs1452510913, COSV100971960; called by muse, varscan2
- ADAP1 | c.551T>C p.F184S | Missense Mutation (SNP) | VAF 293/682 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CELF5 | c.350_352del p.R117del | In Frame Del (DEL) | VAF 102/239 reads (43%) | called by mutect2, pindel, varscan2
- CFAP74 | c.4459C>T p.P1487S | Missense Mutation (SNP) | VAF 364/692 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); called by muse, varscan2
- CWC22 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 135/348 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.094); called by muse, varscan2
- HCFC1 | c.5933C>A p.A1978D | Missense Mutation (SNP) | VAF 371/402 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2A | c.6408T>A p.Y2136* | Nonsense Mutation (SNP) | VAF 268/610 reads (44%) | called by muse, varscan2
- MAPK8IP3 | c.1931G>C p.R644P | Missense Mutation (SNP) | VAF 319/782 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, varscan2
- SPRY2 | c.632A>T p.N211I | Missense Mutation (SNP) | VAF 26/686 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- ZC3H13 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 285/638 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ALPK3 | c.4857G>T p.L1619= | Silent (SNP) | VAF 258/542 reads (48%) | called by muse, varscan2
- C22orf23 | c.166+100dup | Intron (INS) | VAF 26/108 reads (24%) | catalogued as rs1404934491; called by mutect2, varscan2
- ZNF518A | c.*48_*49insTA | 3'UTR (INS) | VAF 62/181 reads (34%) | called by mutect2, pindel, varscan2
